Surgical pathology report (de-identified scan), TCGA case TCGA-06-0159, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0159-01A (Primary Tumor).

Patient Name: (

MRN: (

Sex: (

Room/Bed:

Ambulatory Surgeon:

PATH.NO: .

MED. REC. NO: ' .

SURGERY DATE:

RECEIVE DATE:

UUID: SC189EAA-AD1E-4957-B2F4-E253BC9953C7

NAME:

AGE/SEX: M DOB: \

PHYSICIAN:

COPY TO:

UPDATED REPORT

- SEE ADDENDUM DIAGNOSIS.

PATHOLOGICAL DIAGNOSIS:

BRAIN, OCCIPITAL, EXCISIONAL BIOPSIES: GLIOBLASTOMA MULTIFORME.

ADDENDUM DIAGNOSIS: BRAIN, OCCIPITAL, EXCISIONAL BIOPSIES:
GLIOBLASTOMA MULTIFORME. MIB-1 LABELLING INDEX 20%.

Operation/Specimen: Brain, occipital.

Clinical History and Pre-Op Dx: The patient is a year-old man with short history of headache and visual disturbances who has heterogenous, ring enhancing lesion on occipital lobe.

GROSS PATHOLOGY: Received fresh, for fragments, 1.5 x 1.5 x 0.4 cm in aggregate. Soft, glistening, grayish-tan. in toto #1-3.

INTRAOPERATIVE CONSULTATION: Brain, Occipital: Malignant Glioma, Consistent With Glioblastoma .

B.

SPECIMEN: Occipital tumor.

FIXATIVE: None.

GENERAL: Two irregular fragments of hemorrhagic to light brown brain tissue 1.2 x 1 x 0.3 cm.

SECTIONS: Entirely submitted, 4,5.

MICROSCOPIC: Portions of a cellular neoplastic glial proliferation with features of cellular anaplasia, frequent mitosis, microvascular cellular proliferation and areas of necrosis.

Part B. Additional tissue of this occipital tumor again shows the features of glioblastoma multiforme with large pleomorphic neoplastic glial cells with necrosis and microvascular proliferation.

TISSUE COMMITTEE CODE:

BILLING CODES:

Source: NCI Genomic Data Commons file ff05cf68-7ca6-49f6-ad5a-68e73976457b (TCGA-06-0159.5C189EAA-AD1E-4957-B2F4-E253BC9953C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).